Somatic mutation profile of tumor specimen 0DNMAV from CCDI case PBCAYE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 15.9 years (5,805 days).
Specimen 0DNMAV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e514d59-cfc2-45b7-9a50-8a78293e40c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNM9X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dae870ae-196f-4b13-ae51-d59ea1df26cf

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Intron 5, Silent 5, Splice Region 2, Splice Site 1, RNA 1, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 564/819 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ATPAF2 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 110/251 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1352572852; called by muse, mutect2, varscan2
- BRI3BP | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 69/473 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765369921; called by muse, mutect2, varscan2
- CCDC172 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs868026474, COSV100319718, COSV100319989, COSV60937199; called by muse, mutect2, varscan2
- CLCNKB | c.1298-1G>T p.X433_splice | Splice Site (SNP) | VAF 181/479 reads (38%) | catalogued as COSV65161724; called by muse, mutect2, varscan2
- CMYA5 | c.7365G>T p.E2455D | Missense Mutation (SNP) | VAF 82/632 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.044); catalogued as COSV71404092; called by muse, mutect2, varscan2
- DOP1A | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52714493; called by muse, mutect2, varscan2
- ELAC2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 136/278 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775958815, COSV62032275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXW7 | c.1751C>G p.T584R (on ENST00000281708 / NM_001349798.2; = p.T504R on NM_018315.5) | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55919828; called by muse, mutect2, varscan2
- GPAT3 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1056284484; called by muse, mutect2, varscan2
- MOV10 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs777118633; called by muse, varscan2
- RYR3 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1400907786, COSV66788410; called by muse, mutect2, varscan2
- TBC1D32 | c.3389A>T p.Y1130F | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.817); catalogued as rs1283163454; called by muse, mutect2, varscan2
- C14orf39 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 126/306 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CNTNAP1 | c.1736-8T>C | Splice Region (SNP) | VAF 21/520 reads (4%) | called by muse, mutect2
- EXD1 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- FAM187B | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 109/513 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GC | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGT5 | c.1041T>C p.N347= | Splice Region (SNP) | VAF 49/415 reads (12%) | called by muse, mutect2, varscan2
- INPP5B | c.2055G>T p.M685I (on ENST00000373023; = p.M605I on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/312 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- IPO5 | c.2848C>A p.L950M | Missense Mutation (SNP) | VAF 30/333 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.921); called by muse, mutect2
- IQGAP3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 148/462 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PACS2 | c.405del p.S136Pfs*7 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | called by mutect2, pindel, varscan2
- PIEZO2 | c.2313dup p.E772Rfs*4 | Frame Shift Ins (INS) | VAF 106/322 reads (33%) | called by mutect2, pindel, varscan2
- PPT2 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS6KL1 | c.128A>T p.D43V | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SF3A1 | c.1666C>G p.Q556E | Missense Mutation (SNP) | VAF 74/572 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SIRT7 | c.449T>A p.M150K | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SUB1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 67/551 reads (12%) | called by muse, mutect2, varscan2
- TLL1 | c.1558C>G p.L520V | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TSPAN14 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 89/321 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.11067G>T p.V3689= | Silent (SNP) | VAF 61/323 reads (19%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.3168G>T p.L1056= | Silent (SNP) | VAF 115/285 reads (40%) | catalogued as COSV100233467; called by muse, mutect2, varscan2
- RAD17 | c.1497G>A p.T499= (on ENST00000380774 / NM_133339.2; = p.T488= on NM_002873.1) | Silent (SNP) | VAF 93/423 reads (22%) | catalogued as rs772310870; called by muse, mutect2, varscan2
- TOLLIP | c.753C>T p.S251= | Silent (SNP) | VAF 61/252 reads (24%) | catalogued as rs752015473; called by muse, mutect2, varscan2
- ZNF99 | c.9G>A p.S3= | Silent (SNP) | VAF 41/287 reads (14%) | catalogued as rs372304348; called by muse, mutect2, varscan2
- AMPD1 | c.1614+91G>A | Intron (SNP) | VAF 53/120 reads (44%) | catalogued as rs965629361; called by muse, mutect2, varscan2
- BCL11A | c.*68G>A | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2
- DMKN | c.1287+88A>C | Intron (SNP) | VAF 111/217 reads (51%) | called by muse, mutect2, varscan2
- DOP1A | c.2870+64T>C | Intron (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- MLEC | c.-62G>T | 5'UTR (SNP) | VAF 20/57 reads (35%) | catalogued as rs914044297; called by muse, mutect2, varscan2
- MST1L | n.991del | RNA (DEL) | VAF 102/781 reads (13%) | called by mutect2, pindel, varscan2
- SUPT5H | c.320-24C>T | Intron (SNP) | VAF 30/170 reads (18%) | catalogued as rs377087269; called by muse, mutect2, varscan2
- ZGRF1 | c.2802+99C>A | Intron (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
